TCGA case TCGA-06-5858 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d1547b99-3c96-4c62-8261-5111bcf860a9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 45.6 years (16,662 days); Year of diagnosis: 2010; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 68 days; Treatment dose: 6,000 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Days to treatment start: 25 days; Days to treatment end: 68 days; Number of cycles: 1; Treatment dose: 150 mg; Prescribed dose: 75; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Veliparib; Treatment intent type: Adjuvant; Days to treatment start: 88 days; Days to treatment end: 88 days; Number of cycles: 1; Treatment dose: 20 mg; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Initial disease status: Progressive Disease; Days to treatment start: 196 days; Treatment dose: 1,014 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 10; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 196 days; Treatment dose: 274 mg; Treatment outcome: Treatment Ongoing; Prescribed dose: 3; Prescribed dose units: mg; Route of administration: Intravenous.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 45.9 years (16,759 days); Days to diagnosis: 97 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 97 (post initial treatment): Progression or recurrence: Yes; Days to progression: 97 days.
- Days to follow up: 187 days; Disease response: With Tumor.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Prior to Adjuvant Therapy.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-5858-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.9; Shortest dimension: 0.9.
  Slide TCGA-06-5858-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 18; Percent stromal cells: 0.
  Slide TCGA-06-5858-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 15; Percent stromal cells: 0.
- Sample TCGA-06-5858-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-5858-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection; Performance status timing: Pre-Adjuvant Therapy.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: ABT-888 Parp Inhibitor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 187 days; disease-specific survival: no event (censored), 187 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 97 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-06-5858-01A-01D-1694-01): tumor purity 1, ploidy 1.08, whole-genome doublings 0.
